Somatic mutation profile of tumor specimen 0DU9N0 from CCDI case PBCKWK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.7 years (3,898 days).
Specimen 0DU9N0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4a93990-1a99-4c84-8c07-7fdb105b5adc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9NH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c8e966c-52fe-4937-b0b3-2a816f31a92e

The open-access MAF lists 29 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 12, Missense Mutation 6, 3'UTR 5, Silent 2, Nonsense Mutation 1, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 299/1543 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 198/1063 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARVCF | c.704C>G p.A235G | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs1186218913; called by muse, mutect2
- BTN2A1 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 45/1128 reads (4%) | catalogued as COSV57002527; called by muse, mutect2
- ARHGEF15 | c.1133A>T p.N378I | Missense Mutation (SNP) | VAF 39/615 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); called by muse, mutect2
- FAM133A | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 78/1592 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 54/1956 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- PCSK5 | c.4259-1G>A p.X1420_splice | Splice Site (SNP) | VAF 81/406 reads (20%) | called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 43/535 reads (8%) | catalogued as rs1167537044; called by muse, mutect2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 34/304 reads (11%) | called by muse, mutect2, varscan2
- ACE | c.3381-75C>T | Intron (SNP) | VAF 6/63 reads (10%) | called by mutect2, varscan2
- ANKK1 | c.*29T>C | 3'UTR (SNP) | VAF 20/338 reads (6%) | catalogued as rs1221286106; called by muse, mutect2
- ATP6V0E2 | c.*19+66C>G | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs920395245, COSV101374590; called by muse, mutect2, varscan2
- CACNB4 | c.*95T>A | 3'UTR (SNP) | VAF 16/159 reads (10%) | called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 27/205 reads (13%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 27/197 reads (14%) | called by muse, varscan2
- CCDC47 | c.548-73T>C | Intron (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- COLEC11 | c.-26-728A>G | Intron (SNP) | VAF 30/475 reads (6%) | called by muse, mutect2
- DNMT1 | c.3476-81T>C | Intron (SNP) | VAF 6/59 reads (10%) | catalogued as COSV104416197; called by muse, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 19/188 reads (10%) | called by muse, varscan2
- FEZ1 | chr11:125496895 A>T | 5'Flank (SNP) | VAF 10/94 reads (11%) | called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/212 reads (12%) | called by muse, varscan2
- SGPP1 | c.*41T>A | 3'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- ST3GAL3 | c.603-96G>C | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, varscan2
- TMEM178B | c.*32_*33insTTT | 3'UTR (INS) | VAF 9/304 reads (3%) | called by muse*, mutect2
- UNK | c.*71G>T | 3'UTR (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2
